Somatic mutation profile of tumor specimen 0DS0ZX from CCDI case PBCHGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,298 days).
Specimen 0DS0ZX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e7cae1e-afde-44af-afe8-cd7c9dd734f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a202fae3-59c3-406d-90e8-40e869173076

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 186/481 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs771306546; called by muse, mutect2, varscan2
- TGFBR1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 463/1080 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66625946; called by muse, mutect2, varscan2
- PKHD1L1 | c.8597A>G p.D2866G | Missense Mutation (SNP) | VAF 299/790 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CATSPER2 | c.-113G>A | 5'UTR (SNP) | VAF 184/431 reads (43%) | catalogued as rs753153645; called by muse, mutect2, varscan2
